FM case AD16753 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Skin.
https://portal.gdc.cancer.gov/cases/1c58e605-ccc7-4599-ad27-565df281b9ee

Male, 60.7 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the skin; primary biopsied or resected from the skin. Sample type: Primary Tumor.
